Gene-level copy-number profile of tumor specimen C3L-05286-03 (profiled together with C3L-05286-04) from CPTAC case C3L-05286, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.2 years (18,323 days).
Specimen C3L-05286-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d5c4437-def7-4e61-af63-4041909a88b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05286-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/03776c01-b969-431b-a758-d3baad7f9353

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 168; copy number 2: 15,616; copy number 3: 16,166; copy number 4: 16,932; copy number 5: 6,108; copy number 6: 1,693; copy number 7: 1,510; copy number 8: 69; copy number 10: 14; copy number 12: 37; copy number 13: 4; copy number 15: 24; copy number 16: 16.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr15:28,545,912–28,685,264, 6 genes (within-gene range 0–1): AC138749.3, AC138749.1, AC138749.2, HERC2P11, HERC2P9, AC055876.2.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–4): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 95 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,397,987–21,825,225, 14 genes, copy number 10 (within-gene range 4–10): PPP1R11P1, AL592309.1, AL592309.2, NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10, ALPL, LINC02596, RAP1GAP, USP48, AL590103.1, LDLRAD2.
- chr1:24,307,556–26,229,840, 65 genes, copy number 12–15 (broad region; genes not listed).
- chr1:51,157,788–51,709,940, 16 genes, copy number 16: CFL1P2, LINC01562, RNF11, AL162430.1, AL162430.2, TTC39A, TTC39A-AS1, EPS15, AL671986.1, RNU6-877P, AC104170.1, EPS15-AS1, RNU6-1281P, CALR4P, GAPDHP51, SLC25A6P3.

Autosomal genes at a single copy (total copy number 1): 107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
